Somatic mutation profile of tumor specimen TCGA-CV-6441-01A (aliquot TCGA-CV-6441-01A-11D-1683-08) from TCGA case TCGA-CV-6441, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 60.3 years (22,025 days).
Specimen TCGA-CV-6441-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 450ae40f-62fe-41c9-ae7a-7ee227a2e098.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6441-11A (Solid Tissue Normal), aliquot TCGA-CV-6441-11A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0c36ddd-07c3-40b9-a08a-98cf03db0a94

The open-access MAF lists 250 somatic variants for this specimen: 180 protein-altering or splice-affecting, 62 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 151, Silent 62, Nonsense Mutation 15, Frame Shift Del 5, Intron 3, Frame Shift Ins 3, Splice Region 3, RNA 2, In Frame Del 2, 5'Flank 2, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.386G>A p.C129Y | Missense Mutation (SNP) | VAF 60/85 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1566935517, CM950436, COSV57318510; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.8059C>T p.R2687* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as rs1555191598, CM122093, COSV56441698; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.2272G>C p.G758R (on ENST00000404938 / NM_001163941.2; = p.G313R on NM_178559.6) | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51723348, COSV99327421; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2025G>A p.W675* | Nonsense Mutation (SNP) | VAF 10/12 reads (83%) | catalogued as rs1468134931, COSV101001303; called by muse, mutect2, varscan2
- AFMID | c.126G>C p.L42F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV100014816; called by muse, mutect2, varscan2
- AGO1 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as COSV100940755; called by muse, mutect2, varscan2
- AK5 | c.96A>C p.E32D (on ENST00000354567 / NM_174858.3; = p.E6D on NM_012093.4) | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV58357197; called by muse, mutect2, varscan2
- ANKRD50 | c.1628C>G p.S543* | Nonsense Mutation (SNP) | VAF 43/58 reads (74%) | catalogued as COSV101538885; called by muse, mutect2, varscan2
- ANKS1B | c.2063G>T p.G688V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.864); catalogued as COSV100242974, COSV61349472; called by muse, mutect2
- AQP6 | c.287C>G p.S96C | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1187355615, COSV100210072; called by muse, mutect2
- ARHGEF26 | c.2522C>G p.P841R | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100726384; called by muse, mutect2, varscan2
- ATP11A | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV52111679; called by muse, varscan2
- ATP11A | c.391C>A p.H131N | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV99367457; called by muse, varscan2
- C12orf4 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.543); catalogued as COSV99712549; called by muse, mutect2, varscan2
- C22orf15 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV100533545; called by muse, mutect2, varscan2
- C9orf131 | c.1808C>T p.P603L | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV100397910; called by muse, mutect2, varscan2
- C9orf131 | c.2083C>G p.L695V | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.677); catalogued as COSV100397857, COSV100397911; called by muse, mutect2, varscan2
- CASP14 | c.161G>C p.R54T | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.259); catalogued as COSV99692901; called by muse, mutect2, varscan2
- CCDC40 | c.1180A>G p.M394V | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99481297; called by muse, mutect2, varscan2
- CCND1 | c.844G>C p.D282H | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV99919224; called by muse, varscan2
- CD1B | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 88/422 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV100939139; called by muse, mutect2, varscan2
- CDCA7 | c.551G>T p.R184M (on ENST00000347703 / NM_145810.3; = p.R263M on NM_031942.5) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV100143329; called by muse, mutect2
- CDH10 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100053608, COSV52572125; called by muse, mutect2
- CDK12 | c.1508C>G p.S503C | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV101420370; called by muse, mutect2, varscan2
- CENPN | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV100001129; called by muse, mutect2, varscan2
- CFAP251 | c.2779G>A p.E927K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV99995717; called by muse, mutect2, varscan2
- CFAP46 | c.7202G>T p.R2401L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV99583945; called by muse, mutect2, varscan2
- CLK3 | c.1802T>G p.L601* (on ENST00000395066 / NM_001130028.1; = p.L453* on NM_003992.4) | Nonsense Mutation (SNP) | VAF 24/29 reads (83%) | catalogued as COSV100165768; called by muse, mutect2, varscan2
- CNGB1 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.036); catalogued as COSV99201421; called by muse, mutect2, varscan2
- COL11A1 | c.1543C>T p.Q515* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100615146; called by muse, mutect2, varscan2
- COL4A3 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.111); catalogued as COSV101169939; called by muse, mutect2
- CPAMD8 | c.2032C>T p.R678W (on ENST00000651564; = p.R631W on NM_015692.5) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs367916283; called by muse, mutect2, varscan2
- CXXC1 | c.221G>C p.R74T | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV99495454; called by muse, varscan2
- DCDC2B | c.510G>C p.Q170H | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV99356309; called by muse, mutect2
- DNAH11 | c.4909C>G p.L1637V | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100177133; called by muse, mutect2, varscan2
- DNAH2 | c.12903C>T p.N4301= | Splice Region (SNP) | VAF 178/222 reads (80%) | catalogued as rs1392573341, COSV101209010; called by muse, mutect2, varscan2
- DNAH5 | c.1850C>T p.A617V | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.141); catalogued as COSV99445116; called by muse, mutect2, varscan2
- DNM1L | c.1601C>G p.S534C | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV99845770; called by muse, mutect2, varscan2
- DPP3 | c.1993C>T p.R665C | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs200243081, COSV64756965; called by muse, mutect2
- DPY19L2 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769377930, COSV100116522; called by muse, mutect2, varscan2
- DRD3 | c.947A>C p.Q316P | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.761); catalogued as COSV99879171; called by muse, mutect2, varscan2
- EHD1 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV100276846; called by muse, mutect2
- EIF3B | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100703551; called by muse, mutect2, varscan2
- EIF3L | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101094433; called by muse, mutect2, varscan2
- ELK4 | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.203); catalogued as COSV99222246; called by muse, mutect2, varscan2
- ELP4 | c.610T>G p.F204V (on ENST00000350638; = p.F203V on NM_019040.5) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV100635103; called by muse, mutect2, varscan2
- ENY2 | c.18G>A p.M6I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV99516703; called by muse, mutect2, varscan2
- EPHA3 | c.2405C>G p.T802R | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369423490, COSV100345989; called by muse, mutect2, varscan2
- EPHA5 | c.986A>T p.H329L | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99896227; called by muse, mutect2, varscan2
- EPHA5 | c.985C>A p.H329N | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99896230; called by muse, mutect2, varscan2
- FAM110B | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as COSV100826010; called by muse, mutect2, varscan2
- FAM214A | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV99957611; called by muse, mutect2, varscan2
- FAT1 | c.3152C>G p.S1051* | Nonsense Mutation (SNP) | VAF 55/83 reads (66%) | catalogued as COSV101499020; called by muse, mutect2, varscan2
- FGF20 | c.393G>C p.E131D | Missense Mutation (SNP) | VAF 49/194 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs765043985, COSV51661607, COSV99471465; called by muse, mutect2, varscan2
- FLNA | c.703T>A p.W235R | Missense Mutation (SNP) | VAF 66/90 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100774278; called by muse, mutect2, varscan2
- GALNT5 | c.2124G>A p.M708I | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99374842; called by muse, mutect2
- GIPR | c.1055T>C p.V352A | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs1490061680; called by muse, mutect2
- GLI2 | c.1282A>G p.T428A (on ENST00000361492 / NM_001374353.1; = p.T445A on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV100082350; called by muse, mutect2, varscan2
- GPR161 | c.1142G>A p.G381E | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99606223; called by muse, mutect2, varscan2
- H1-2 | c.504G>C p.K168N | Missense Mutation (SNP) | VAF 73/106 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs534420299, COSV100642298, COSV59189505; called by muse, mutect2, varscan2
- HAPLN1 | c.622G>T p.G208C | Missense Mutation (SNP) | VAF 50/63 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868346551, COSV57149252, COSV57152635; called by muse, mutect2, varscan2
- HDAC3 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100539409; called by muse, mutect2, varscan2
- HEYL | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs139668981; called by muse, mutect2, varscan2
- HFM1 | c.172C>T p.H58Y | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV99645360; called by muse, mutect2
- HGF | c.1048C>T p.R350* | Nonsense Mutation (SNP) | VAF 21/74 reads (28%) | catalogued as COSV99735605; called by muse, mutect2, varscan2
- HTR7 | c.1294C>T p.L432= | Splice Region (SNP) | VAF 44/162 reads (27%) | catalogued as rs760898658, COSV99518957; called by muse, mutect2, varscan2
- HTR7 | c.1293G>T p.V431= | Splice Region (SNP) | VAF 46/166 reads (28%) | catalogued as COSV99518958; called by muse, mutect2, varscan2
- ICE1 | c.3581C>G p.S1194C | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV99663754; called by muse, mutect2
- IGSF9B | c.2836C>G p.R946G | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs778188740, COSV100316994; called by muse, mutect2, varscan2
- ING3 | c.1138G>C p.D380H | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100253096; called by muse, mutect2, varscan2
- ITGA10 | c.2094G>C p.M698I | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100994710; called by muse, mutect2, varscan2
- JMJD1C | c.2794C>A p.P932T | Missense Mutation (SNP) | VAF 62/109 reads (57%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.822); catalogued as COSV100550125; called by muse, mutect2, varscan2
- KCNB1 | c.1933G>C p.D645H | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV100870382; called by muse, mutect2, varscan2
- KIF19 | c.2018C>G p.S673* | Nonsense Mutation (SNP) | VAF 18/117 reads (15%) | catalogued as COSV100738944; called by muse, mutect2, varscan2
- KIF3B | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.076); catalogued as COSV100996318; called by muse, mutect2, varscan2
- KLF3 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV99789611; called by muse, mutect2, varscan2
- LAMA5 | c.10927C>G p.L3643V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.426); catalogued as COSV99438055; called by muse, mutect2
- LFNG | c.1063G>A p.D355N (on ENST00000222725 / NM_001040167.2; = p.D226N on NM_002304.2) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780649312, COSV99761661; called by muse, mutect2, varscan2
- LPCAT1 | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 22/594 reads (4%) | catalogued as COSV99358749; called by muse, mutect2
- LPL | c.518A>T p.N173I | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.367); catalogued as COSV100255298; called by muse, mutect2, varscan2
- LRRC37A | c.4270G>A p.E1424K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.899); catalogued as COSV100208095; called by muse, mutect2, varscan2
- MAGEA4 | c.160G>A p.V54M | Missense Mutation (SNP) | VAF 42/53 reads (79%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV99367282; called by muse, mutect2, varscan2
- MARCO | c.267G>C p.E89D | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100503198; called by muse, mutect2, varscan2
- MARK4 | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as rs1166918249, COSV99487854; called by muse, mutect2, varscan2
- MDGA2 | c.2066G>A p.G689E (on ENST00000399232 / NM_001113498.2; = p.G391E on NM_182830.4) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as COSV100636409; called by muse, mutect2
- MICAL3 | c.37C>G p.H13D | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99259925; called by muse, varscan2
- MYH2 | c.2949C>A p.N983K | Missense Mutation (SNP) | VAF 105/200 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99819268; called by muse, mutect2, varscan2
- NBPF10 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.196); catalogued as COSV100744026; called by muse, mutect2, varscan2
- NCAPG | c.1674G>C p.Q558H | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99265646; called by muse, mutect2, varscan2
- NCOR1 | c.505C>G p.Q169E | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as COSV99247337; called by muse, varscan2
- NCOR1 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV51973391; called by muse, varscan2
- NCOR2 | c.7024A>G p.I2342V | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100656858; called by muse, mutect2, varscan2
- NDUFAF7 | c.125C>G p.P42R | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV99135413; called by muse, mutect2
- NID2 | c.175G>T p.V59L | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs1375780357, COSV99355959; called by muse, mutect2, varscan2
- NLRP8 | c.2432A>C p.N811T | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV99404722; called by muse, mutect2, varscan2
- NMT1 | c.177G>C p.K59N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.264); catalogued as COSV51959271, COSV99364587; called by muse, mutect2, varscan2
- NR2F2 | c.308T>G p.F103C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101240917; called by muse, mutect2, varscan2
- NSD1 | c.974A>T p.D325V | Missense Mutation (SNP) | VAF 44/61 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV100728417; called by muse, mutect2, varscan2
- NYAP2 | c.770G>A p.R257K | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs781748171, COSV99795745; called by muse, mutect2, varscan2
- OR51G1 | c.628G>A p.G210S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100429132, COSV100429202; called by muse, mutect2, varscan2
- OR5H14 | c.89C>A p.A30E | Missense Mutation (SNP) | VAF 88/311 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV101454070; called by muse, mutect2, varscan2
- OR6C4 | c.419T>C p.I140T | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.007); catalogued as COSV101263124; called by muse, mutect2, varscan2
- OR6N1 | c.317C>A p.S106Y | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100625076, COSV100625323; called by muse, mutect2, varscan2
- OR8H2 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV57946880, COSV57947982; called by muse, mutect2, varscan2
- PAEP | c.233G>A p.R78K | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.097); catalogued as COSV99478841; called by muse, mutect2, varscan2
- PAK1IP1 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.309); catalogued as COSV101093328; called by muse, mutect2, varscan2
- PCDHA8 | c.1185C>G p.F395L | Missense Mutation (SNP) | VAF 45/241 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100970432; called by muse, mutect2, varscan2
- PHF13 | c.505T>G p.S169A | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV99275432; called by muse, mutect2, varscan2
- PLXNB2 | c.1798C>T p.R600* | Nonsense Mutation (SNP) | VAF 61/82 reads (74%) | catalogued as rs1333488993, COSV63780558; called by muse, mutect2, varscan2
- PNPLA8 | c.954G>C p.K318N | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV57552019; called by muse, mutect2, varscan2
- PRDM1 | c.627C>G p.H209Q | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100958546; called by muse, mutect2, varscan2
- PSG8 | c.14C>G p.S5* | Nonsense Mutation (SNP) | VAF 20/93 reads (22%) | catalogued as COSV100125980; called by muse, mutect2, varscan2
- PTCD3 | c.1548T>G p.S516R | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); catalogued as COSV99605991; called by muse, mutect2, varscan2
- PTPRD | c.3441G>C p.L1147F | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as COSV100643362, COSV100647840; called by muse, mutect2, varscan2
- QKI | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.061); catalogued as COSV99274267; called by muse, mutect2
- RAB25 | c.294G>T p.Q98H | Missense Mutation (SNP) | VAF 73/154 reads (47%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.473); catalogued as COSV100737282; called by muse, mutect2, varscan2
- RAPGEF6 | c.323T>A p.L108H | Missense Mutation (SNP) | VAF 76/93 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV99725262; called by muse, mutect2, varscan2
- RAPH1 | c.1811C>T p.S604L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.879); catalogued as COSV99863391; called by muse, mutect2, varscan2
- REN | c.1013T>C p.L338P | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99689402; called by muse, mutect2, varscan2
- RLF | c.1309G>C p.D437H | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101035087; called by muse, mutect2, varscan2
- RSAD2 | c.227A>G p.N76S | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101149758; called by muse, mutect2, varscan2
- RWDD2B | c.375G>C p.L125F | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV99725515; called by muse, mutect2, varscan2
- SAMHD1 | c.1486G>T p.E496* | Nonsense Mutation (SNP) | VAF 24/146 reads (16%) | catalogued as COSV99483786; called by muse, mutect2, varscan2
- SAXO1 | c.1148C>A p.P383H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV101000094; called by muse, mutect2, varscan2
- SIGLEC7 | c.778A>C p.N260H | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99978447; called by muse, mutect2, varscan2
- SLC12A6 | c.1650G>T p.K550N (on ENST00000354181 / NM_001365088.1; = p.K499N on NM_005135.2) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV99271029; called by muse, mutect2, varscan2
- SLC26A5 | c.394A>C p.I132L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV100098651; called by muse, mutect2, varscan2
- SLC2A2 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as rs368626129; called by muse, mutect2, varscan2
- SLIT2 | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs780111778, COSV56564001; called by muse, mutect2, varscan2
- SLITRK6 | c.1144G>T p.D382Y | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68389797, COSV68390247; called by muse, mutect2, varscan2
- SNTG1 | c.1426C>G p.L476V | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99381356; called by muse, mutect2, varscan2
- SNX25 | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV99252362; called by muse, mutect2, varscan2
- SPAG17 | c.145C>G p.L49V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.246); catalogued as COSV100307956; called by muse, mutect2, varscan2
- SPEG | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372300281; called by muse, varscan2
- ST13 | c.245-1G>A p.X82_splice | Splice Site (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99343975; called by muse, mutect2, varscan2
- ST3GAL4 | c.154G>A p.E52K (on ENST00000392669 / NM_001254758.1; = p.E48K on NM_006278.3) | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.031); catalogued as COSV99917261; called by muse, mutect2, varscan2
- STK25 | c.1170C>G p.F390L | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as COSV99883905; called by muse, mutect2, varscan2
- STXBP5L | c.1001C>A p.A334D | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV99872058; called by muse, mutect2, varscan2
- STXBP5L | c.2787G>A p.W929* | Nonsense Mutation (SNP) | VAF 11/91 reads (12%) | catalogued as COSV56524058, COSV56534438; called by muse, varscan2
- SUN3 | c.533G>C p.R178T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1396565875, COSV99813832; called by muse, mutect2, varscan2
- TBX6 | c.424G>C p.D142H | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM154546, COSV99661497; called by muse, mutect2, varscan2
- TDRD5 | c.96G>C p.E32D | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54239462, COSV99675454; called by muse, mutect2, varscan2
- TGS1 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as rs139226926; called by muse, mutect2
- THSD7A | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101448543; called by muse, mutect2, varscan2
- TMPRSS11D | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 21/54 reads (39%) | catalogued as rs201111407, COSV52224309; called by muse, mutect2, varscan2
- TMSB4Y | c.30C>G p.I10M | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); catalogued as COSV99514861; called by muse, mutect2, varscan2
- TNN | c.3809T>C p.V1270A | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV99511094; called by muse, mutect2, varscan2
- TNS3 | c.191T>C p.L64P | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100234748; called by muse, mutect2, varscan2
- TRIM46 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.057); catalogued as COSV58114802; called by muse, mutect2, varscan2
- TRIM54 | c.610G>T p.D204Y (on ENST00000380075 / NM_187841.3; = p.D246Y on NM_032546.4) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV99274161; called by muse, mutect2
- TRMT10A | c.566A>G p.D189G | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV99910820; called by muse, mutect2, varscan2
- TTBK1 | c.1454C>T p.S485L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as rs1050745819, COSV52495669; called by muse, mutect2, varscan2
- TTC7A | c.2115G>T p.Q705H | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.46); catalogued as COSV99766007; called by muse, mutect2, varscan2
- TTN | c.75529G>A p.E25177K (on ENST00000591111; = p.E17753K on NM_003319.4) | Missense Mutation (SNP) | VAF 24/158 reads (15%) | PolyPhen probably damaging (0.995); catalogued as COSV100594395; called by muse, mutect2, varscan2
- TTN | c.42599T>A p.V14200D (on ENST00000591111; = p.V6776D on NM_003319.4) | Missense Mutation (SNP) | VAF 47/129 reads (36%) | PolyPhen benign (0.238); catalogued as COSV100594401; called by muse, mutect2, varscan2
- TUFT1 | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100777018; called by muse, mutect2, varscan2
- TXNL1 | c.425A>C p.D142A | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99469421; called by muse, varscan2
- UGT2B28 | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV100158552, COSV59431889; called by muse, mutect2, varscan2
- UGT2B7 | c.1537C>G p.L513V | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV100535106; called by muse, mutect2, varscan2
- VRK3 | c.888C>G p.F296L | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV100371300; called by muse, mutect2, varscan2
- ZC3H4 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV99451710; called by muse, mutect2, varscan2
- ZNF10 | c.716A>T p.K239I | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99939847; called by muse, mutect2, varscan2
- ZNF239 | c.944G>C p.G315A | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100021702; called by muse, mutect2, varscan2
- ZNF257 | c.563T>A p.L188Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV101448016; called by muse, mutect2, varscan2
- ZNF281 | c.961C>T p.Q321* | Nonsense Mutation (SNP) | VAF 137/326 reads (42%) | catalogued as COSV99664000; called by muse, mutect2, varscan2
- ZNF334 | c.19C>A p.Q7K | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV100748977; called by muse, mutect2, varscan2
- ZNF385B | c.558G>T p.Q186H | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV100415768; called by muse, mutect2, varscan2
- ZNF513 | c.1577C>A p.P526Q | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); catalogued as rs376865509, COSV99277261; called by muse, mutect2, varscan2
- ZNF780A | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 39/56 reads (70%) | SIFT tolerated (0.14); PolyPhen benign (0.059); catalogued as COSV61815824; called by muse, mutect2, varscan2
- ZNFX1 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as rs778680326, COSV65577544; called by muse, mutect2, varscan2
- DIP2C | c.4284del p.D1428Efs*13 | Frame Shift Del (DEL) | VAF 20/102 reads (20%) | called by mutect2, pindel*, varscan2
- H1-2 | c.108dup p.G37Wfs*16 | Frame Shift Ins (INS) | VAF 32/55 reads (58%) | called by mutect2, pindel, varscan2
- NPHP4 | c.1272_1275del p.K424Nfs*6 | Frame Shift Del (DEL) | VAF 22/88 reads (25%) | called by mutect2, pindel, varscan2
- POR | c.900dup p.R301Afs*18 | Frame Shift Ins (INS) | VAF 23/102 reads (23%) | called by mutect2, pindel, varscan2
- PTPRT | c.1086del p.T363Hfs*34 | Frame Shift Del (DEL) | VAF 21/128 reads (16%) | called by mutect2, pindel, varscan2
- RAP1B | c.47del p.K16Sfs*4 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- RARG | c.528_540del p.P177Sfs*2 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | called by mutect2, pindel, varscan2
- STPG3 | c.50_52del p.I17del | In Frame Del (DEL) | VAF 119/152 reads (78%) | called by mutect2, pindel, varscan2
- TRAV19 | c.210_212del p.R71del | In Frame Del (DEL) | VAF 6/32 reads (19%) | called by pindel, varscan2
- TTN | c.53594dup p.D17865Efs*2 (on ENST00000591111; = p.D10441Efs*2 on NM_003319.4) | Frame Shift Ins (INS) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- ABCA5 | c.1569G>A p.L523= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV101201005; called by muse, mutect2, varscan2
- ACSS1 | c.1686C>T p.T562= | Silent (SNP) | VAF 44/83 reads (53%) | catalogued as rs779037733, COSV100054143, COSV60217884; called by muse, mutect2, varscan2
- ADAR | c.1578G>A p.Q526= | Silent (SNP) | VAF 18/125 reads (14%) | catalogued as COSV52716502; called by muse, mutect2, varscan2
- AGO1 | c.1368C>A p.P456= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV100940756, COSV64595294; called by muse, mutect2, varscan2
- AHNAK2 | c.9681C>G p.P3227= | Silent (SNP) | VAF 38/492 reads (8%) | catalogued as rs767567480, COSV100315595; called by muse, mutect2
- ALDH1A3 | c.1173C>G p.L391= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100320242; called by mutect2, varscan2
- ALYREF | c.414G>A p.T138= | Silent (SNP) | VAF 53/69 reads (77%) | catalogued as rs1216994313, COSV100485755; called by muse, mutect2, varscan2
- ASB10 | c.717A>G p.A239= (on ENST00000420175 / NM_001142459.2; = p.A224= on NM_080871.4) | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99318159; called by muse, mutect2, varscan2
- ATXN2L | c.1920C>T p.I640= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV100293562; called by muse, mutect2, varscan2
- BAZ2B | c.4737A>G p.S1579= | Silent (SNP) | VAF 50/131 reads (38%) | catalogued as COSV100600374; called by muse, mutect2, varscan2
- BRAP | c.1050G>A p.E350= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV100553962; called by muse, mutect2, varscan2
- CCDC105 | c.1239G>A p.A413= | Silent (SNP) | VAF 28/44 reads (64%) | catalogued as rs201682023; called by muse, mutect2, varscan2
- CCDC80 | c.714G>A p.L238= | Silent (SNP) | VAF 19/139 reads (14%) | catalogued as rs1363922966, COSV52816274, COSV52820477; called by muse, mutect2, varscan2
- CILP | c.1785A>G p.E595= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as rs1314499612, COSV99972796; called by muse, mutect2, varscan2
- CMYA5 | c.12012G>A p.E4004= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV101405640; called by muse, mutect2, varscan2
- CUBN | c.1122T>A p.P374= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV100912055; called by muse, varscan2
- DAPK3 | c.360C>G p.L120= | Silent (SNP) | VAF 31/109 reads (28%) | catalogued as COSV56663692; called by muse, mutect2, varscan2
- E4F1 | c.93G>A p.A31= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as rs982072745, COSV100065385; called by muse, mutect2, varscan2
- ENKUR | c.300G>A p.Q100= | Silent (SNP) | VAF 28/132 reads (21%) | catalogued as COSV58634582; called by muse, mutect2, varscan2
- GLI3 | c.957G>A p.T319= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs780215756, COSV101229727; called by muse, mutect2, varscan2
- GPR61 | c.393C>G p.L131= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as rs772546521, COSV101344394; called by muse, mutect2, varscan2
- GRIK5 | c.1248C>T p.T416= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs371342969, COSV99491347; called by muse, mutect2, varscan2
- H2BC12 | c.213C>T p.F71= | Silent (SNP) | VAF 92/134 reads (69%) | catalogued as rs940566780, COSV100804565, COSV63616725; called by muse, mutect2, varscan2
- HGS | c.1974C>T p.P658= | Silent (SNP) | VAF 55/63 reads (87%) | catalogued as rs370738298; called by muse, mutect2, varscan2
- IL3RA | c.468G>A p.T156= | Silent (SNP) | VAF 96/262 reads (37%) | catalogued as rs1445376991, COSV58430704; called by muse, mutect2, varscan2
- INTS7 | c.2730G>A p.V910= | Silent (SNP) | VAF 31/146 reads (21%) | catalogued as COSV100877384; called by muse, mutect2, varscan2
- KLRG1 | c.405G>A p.L135= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99868061; called by muse, mutect2, varscan2
- KNDC1 | c.3696C>T p.L1232= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV100463354; called by muse, mutect2, varscan2
- KRT6A | c.894G>A p.L298= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV100416688; called by muse, mutect2, varscan2
- LDLR | c.2187A>G p.L729= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as CD108090, COSV99369542; called by muse, mutect2, varscan2
- LGR6 | c.2355C>G p.L785= (on ENST00000367278 / NM_001017403.1; = p.L733= on NM_021636.3) | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as COSV99706045; called by muse, mutect2, varscan2
- LOX | c.831C>T p.F277= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV99140593; called by muse, mutect2, varscan2
- LRP1B | c.4960C>T p.L1654= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as COSV67188616, COSV67276520; called by muse, mutect2, varscan2
- MAB21L1 | c.94C>A p.R32= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as COSV100076851; called by muse, mutect2, varscan2
- MCM4 | c.2250T>A p.S750= | Silent (SNP) | VAF 13/184 reads (7%) | catalogued as COSV100031256; called by muse, mutect2
- MICAL3 | c.396C>T p.F132= | Silent (SNP) | VAF 38/140 reads (27%) | catalogued as COSV99259917; called by muse, varscan2
- MPPED1 | c.855C>A p.I285= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV101342209; called by muse, mutect2, varscan2
- MYO15A | c.9300G>A p.L3100= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99231167; called by muse, mutect2, varscan2
- NLRP13 | c.2736C>G p.V912= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV100738039; called by muse, mutect2, varscan2
- NTNG1 | c.183G>A p.L61= | Silent (SNP) | VAF 22/124 reads (18%) | catalogued as COSV53974648; called by muse, mutect2, varscan2
- PAG1 | c.249G>A p.Q83= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV99597004; called by muse, mutect2, varscan2
- PLCE1 | c.1371C>G p.L457= | Silent (SNP) | VAF 68/136 reads (50%) | catalogued as COSV99593531; called by muse, mutect2, varscan2
- POLR3A | c.2151G>A p.L717= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV100965538, COSV64931523; called by muse, mutect2, varscan2
- POPDC3 | c.660C>T p.L220= | Silent (SNP) | VAF 50/151 reads (33%) | catalogued as COSV99633373; called by muse, mutect2, varscan2
- SLC5A7 | c.1227T>C p.S409= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV99886225; called by muse, mutect2, varscan2
- STAT1 | c.348G>T p.L116= | Silent (SNP) | VAF 40/86 reads (47%) | catalogued as COSV100738446; called by muse, mutect2, varscan2
- SUGP1 | c.18C>T p.D6= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as rs1219560675, COSV99448286; called by muse, mutect2, varscan2
- SYBU | c.738T>C p.R246= (on ENST00000276646 / NM_001099754.2; = p.R245= on NM_017786.6) | Silent (SNP) | VAF 33/158 reads (21%) | catalogued as COSV99405689; called by muse, mutect2, varscan2
- SYDE2 | c.3078C>T p.L1026= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100415589; called by muse, mutect2, varscan2
- THADA | c.690G>A p.L230= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV100367943; called by muse, mutect2, varscan2
- TMEM109 | c.489G>C p.L163= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as COSV99133953; called by muse, mutect2, varscan2
- TMEM267 | c.234A>T p.G78= | Silent (SNP) | VAF 37/176 reads (21%) | catalogued as COSV101230975; called by muse, mutect2, varscan2
- TRAPPC8 | c.2223A>G p.S741= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV99350554; called by muse, mutect2, varscan2
- TTC7A | c.2116C>T p.L706= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as COSV99766013; called by muse, mutect2, varscan2
- UGT1A6 | c.816C>T p.V272= | Silent (SNP) | VAF 275/701 reads (39%) | catalogued as COSV100529534; called by muse, mutect2, varscan2
- UNC13C | c.6147T>C p.H2049= | Silent (SNP) | VAF 67/86 reads (78%) | catalogued as COSV99511804; called by muse, mutect2, varscan2
- VGF | c.1650C>T p.I550= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV99972833; called by muse, mutect2, varscan2
- VIM | c.1329G>A p.L443= | Silent (SNP) | VAF 71/200 reads (36%) | catalogued as rs371063888, COSV99812876; called by muse, mutect2, varscan2
- ZBED8 | c.885G>C p.V295= | Silent (SNP) | VAF 32/138 reads (23%) | catalogued as COSV101283461; called by muse, mutect2, varscan2
- ZNF202 | c.225G>A p.L75= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV60246760; called by muse, mutect2, varscan2
- ZNF516 | c.537C>T p.C179= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs775401032, COSV101487208; called by muse, mutect2, varscan2
- ZNF80 | c.222G>A p.V74= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100351913; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81149700 C>G | 5'Flank (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500911 del GG | 5'Flank (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel, varscan2
- C2orf83 | n.485_497del | RNA (DEL) | VAF 12/104 reads (12%) | called by mutect2, pindel
- ECM2 | chr9:92494111 C>T | 3'Flank (SNP) | VAF 14/81 reads (17%) | catalogued as COSV100755789; called by muse, mutect2, varscan2
- LINC01600 | n.864C>T | RNA (SNP) | VAF 52/133 reads (39%) | catalogued as rs547228602; called by muse, mutect2, varscan2
- RMDN2 | c.452+22111C>A | Intron (SNP) | VAF 31/167 reads (19%) | catalogued as COSV99307294; called by muse, mutect2, varscan2
- ROBO1 | c.173-79491G>C | Intron (SNP) | VAF 12/20 reads (60%) | catalogued as COSV101458296; called by muse, mutect2, varscan2
- TTN | c.10360+1659dup | Intron (INS) | VAF 44/141 reads (31%) | called by mutect2, pindel, varscan2
